Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1YC, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1YC-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3 8340/3
DEPARTMENT OF PATHOLOGY CQCF: Carcinoma, papillary, follicular variant
Path: Carcinoma, papillary, thyroid 8260/3
Site: thyroid, nos C73.9
3/6/11 *hw*

Surgical Pathology Consultation Report

Patient Name: _____ Accession #: _____
MRN: _____ Service: _____ Collected: _____
DOB: _____ Visit #: _____ Received: _____
Gender: F Location: _____ Reported: _____
HCN: _____ Facility: _____
Ordering MD: _____
Copy To: _____

Specimen(s) Received

1. Thyroid: right hemithyroid stitch on right upper pole for fresh tumour banking

Diagnosis

Vasculo-invasive oncocytic papillary carcinoma, 6.1cm: Thyroid
No pathological diagnosis: Lymph node, isthmus
- (right) hemithyroidectomy specimen

Synoptic Data

Specimen Type:	Right Hemi-Thyroidectomy
Tumour Focality:	Unifocal
Histologic Type:	Papillary carcinoma, oncocytic type
Tumour Site:	Right Lobe
Tumour Size:	Greatest Dimension: 6.1 cm
Capsular Invasion:	Encapsulated
	Non-invasive
Extrathyroidal Extension:	Absent
Margins:	Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Present
Pathologic Staging (pTNM):	pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)
	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 1
	Number of regional lymph nodes involved: 0
	PMX: Distant metastasis cannot be assessed
Additional Pathologic Findings:	None Identified

Comment

*Pw TSS on 2/2013, TCGA tumor is > 99% follicular variant. *hw**

by: _____

Electronically verified

MD

[page 2 of 2]
Clinical History

thyroid nodule right

Gross Description

1. The specimen labeled with the patient's name and as "Thyroid: Right hemithyroid stitch on right upper pole for fresh tumor banking", consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 42.2 g. The lobe measures 7.5 cm SI x 4.8 cm ML x 2.0 cm AP and the isthmus measures 1.8 SI x 1.5 cm ML x 0.4 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The majority of the lobe is replaced by a nodule that measures 6.1 cm SI x 4.8 cm ML x 2.0 cm AP. There is a rim of compressed thyroid tissue. Multiple sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-J lobe, superior to inferior

1K-L isthmus

Source: NCI Genomic Data Commons file 6c44296a-3f57-49d4-bdfd-6d40086f1727 (TCGA-EM-A1YC.EBE0695F-D5AB-40E1-86B8-AA2B98C4986B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).